Somatic mutation profile of tumor specimen TCGA-L5-A8NL-01A (aliquot TCGA-L5-A8NL-01A-12D-A37C-09) from TCGA case TCGA-L5-A8NL, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 56.2 years (20,542 days).
Specimen TCGA-L5-A8NL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27e2a8cc-23d5-47d9-94c3-35417e8e8ef9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A8NL-11A (Solid Tissue Normal), aliquot TCGA-L5-A8NL-11A-12D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78835097-c5db-42cc-bda7-6d3e8121ecce

The open-access MAF lists 107 somatic variants for this specimen: 81 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 24, Nonsense Mutation 6, Splice Site 2, RNA 2, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- WWOX | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.398); catalogued as rs1131691285; ClinVar: likely pathogenic; called by muse, mutect2
- ADAMTS16 | c.1769C>T p.S590L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1183795725, COSV56997874; called by muse, mutect2, varscan2
- AGBL1 | c.2720A>G p.K907R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV66868237; called by muse, mutect2, varscan2
- APOBEC3G | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs200526446, COSV101349074; called by muse, mutect2, varscan2
- ARID1A | c.1991del p.S664* | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as COSV100250329, COSV61383603; called by mutect2, pindel, varscan2
- BRINP1 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs745883942, COSV56315483; called by muse, mutect2, varscan2
- BRINP2 | c.1872C>A p.C624* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100837810; called by muse, mutect2, varscan2
- CDH12 | c.1609A>C p.N537H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV66393519; called by muse, mutect2, varscan2
- CIITA | c.2942C>T p.T981M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs369744959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DKK2 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs761402051, COSV53394372; called by muse, mutect2, varscan2
- EIF2B5 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as rs1419673400; called by muse, mutect2, varscan2
- EPB41L1 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99148796; called by muse, mutect2, varscan2
- ERC2 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as rs780910111, COSV55607186; called by muse, mutect2, varscan2
- GABBR1 | c.2191G>A p.V731M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as rs776477296, COSV63542701; called by muse, mutect2, varscan2
- GREB1 | c.3760C>T p.R1254C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs368329579; called by muse, mutect2, varscan2
- GTSF1L | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as COSV65932641; called by muse, mutect2, varscan2
- HDAC6 | c.2162G>A p.R721H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.227); catalogued as COSV61929472; called by muse, mutect2, varscan2
- IBSP | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as rs1252338674, COSV56895782, COSV56896429; called by muse, mutect2, varscan2
- IQCN | c.3367G>A p.A1123T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as rs138028745; called by muse, mutect2, varscan2
- KCND2 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as COSV58575204; called by muse, mutect2, varscan2
- KCNQ5 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV59648792; called by muse, mutect2, varscan2
- KIAA1614 | c.3311G>A p.R1104H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.316); catalogued as rs747594621, COSV62551283; called by muse, mutect2, varscan2
- KIF20A | c.2485C>T p.R829C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs752376351; called by muse, mutect2, varscan2
- LRRIQ1 | c.3671A>G p.K1224R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV67825759, COSV67827919; called by muse, mutect2, varscan2
- OR51M1 | c.729A>C p.Q243H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV60785481; called by muse, mutect2
- OR5W2 | c.72A>C p.K24N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV60615220, COSV60618884; called by muse, mutect2, varscan2
- OR8H1 | c.196T>G p.L66V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs776648734, COSV57295726; called by muse, mutect2, varscan2
- OR8K5 | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); catalogued as COSV100537222; called by muse, mutect2, varscan2
- PCDHA5 | c.1867G>A p.V623M | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs138093911; called by muse, mutect2, varscan2
- PDZRN4 | c.662A>C p.K221T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.18); catalogued as COSV68417996; called by muse, mutect2, varscan2
- PPP1R21 | c.2089C>T p.R697* (on ENST00000294952 / NM_001135629.3; = p.R686* on NM_152994.5) | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as rs989639063; called by mutect2, varscan2
- RAB4B | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770414180, COSV100826431, COSV63825153; called by muse, mutect2, varscan2
- RASAL2 | c.428A>G p.E143G | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV62713387, COSV62724111; called by muse, mutect2
- RP1L1 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as rs552894484; called by muse, mutect2, varscan2
- SELENBP1 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs369459403, COSV100923576; called by muse, mutect2, varscan2
- SIPA1L1 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62168879; called by muse, mutect2, varscan2
- SIRPA | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as rs561231326; called by muse, mutect2, varscan2
- SYNE1 | c.24194G>A p.R8065H (on ENST00000367255 / NM_182961.4; = p.R7994H on NM_033071.3) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201956180; called by muse, mutect2, varscan2
- UNC93B1 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1405314727; called by muse, mutect2, varscan2
- WT1 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.29); catalogued as rs756414084, COSV60076977, COSV60082371; ClinVar: uncertain significance; called by mutect2, varscan2
- XPO4 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.421); catalogued as rs769263016; called by muse, mutect2, varscan2
- ZNF219 | c.301C>A p.R101S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV53884463; called by muse, mutect2
- ADGRE2 | c.1038G>T p.K346N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ANKRD30A | c.991T>A p.L331M (on ENST00000611781; = p.L275M on NM_052997.2) | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2
- ARHGEF15 | c.434C>G p.S145* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- ATM | c.3233T>G p.L1078R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP8B2 | c.914T>G p.L305R (on ENST00000672630; = p.L272R on NM_001005855.2) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATPAF1 | c.592C>G p.L198V (on ENST00000574428; = p.L221V on NM_022745.4) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- CDKN1C | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- DCAF1 | c.3316C>T p.R1106W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ELAPOR2 | c.2055G>T p.L685F (on ENST00000450689 / NM_001142749.3; = p.L518F on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- EN1 | c.1019T>A p.L340H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FARSA | c.285+1G>A p.X95_splice | Splice Site (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- FBXL17 | c.1703T>G p.L568R | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GAB3 | c.1700A>C p.K567T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- GALNT17 | c.866A>T p.E289V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- GPR158 | c.1750G>A p.V584I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- H2AC20 | c.334A>T p.I112F | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- IKZF4 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- KCNJ16 | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- KIF3A | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, varscan2
- LOXL2 | c.1637C>T p.T546I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2
- LRP1B | c.4987T>G p.L1663V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LRRC7 | c.278C>T p.A93V (on ENST00000651989 / NM_001370785.2; = p.A60V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAP3K7 | c.784C>G p.L262V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by mutect2, varscan2
- NAP1L3 | c.1318T>C p.F440L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NBEA | c.2561dup p.N854Kfs*18 | Frame Shift Ins (INS) | VAF 8/81 reads (10%) | called by mutect2, pindel
- PPP1R9A | c.2331-2A>C p.X777_splice | Splice Site (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- RAD51AP2 | c.2317A>G p.K773E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- RNF10 | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RPAP2 | c.1769A>T p.E590V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCN5A | c.850T>G p.F284V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.012); called by muse, mutect2
- SH2B3 | c.1310T>A p.M437K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLIT1 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SMCHD1 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- TENM1 | c.3517G>A p.G1173S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by mutect2, varscan2
- TTN | c.48604T>A p.F16202I (on ENST00000591111; = p.F8778I on NM_003319.4) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- USP7 | c.2891dup p.A965Cfs*23 | Frame Shift Ins (INS) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- WASHC4 | c.3314C>T p.T1105I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ZFAT | c.2998C>T p.H1000Y | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ACOT11 | c.1185G>A p.L395= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV56363049; called by muse, mutect2, varscan2
- AMBRA1 | c.2385G>T p.R795= (on ENST00000458649 / NM_001367468.1; = p.R705= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, varscan2
- ANKS1B | c.1881G>T p.G627= | Silent (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- CACNA1H | c.1068C>T p.N356= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs369894677; ClinVar: likely benign; called by muse, mutect2, varscan2
- DLEC1 | c.747C>T p.N249= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs765051280; called by mutect2, varscan2
- DOCK2 | c.5049G>T p.P1683= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV56987552; called by mutect2, varscan2
- EEF1AKNMT | c.759C>G p.A253= (on ENST00000361735 / NM_015935.5; = p.A167= on NM_014955.3) | Silent (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- FOXS1 | c.930C>T p.S310= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as rs139927827; called by muse, mutect2, varscan2
- GPR153 | c.579C>T p.I193= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs537787050, COSV64938741, COSV64939011; called by muse, mutect2, varscan2
- HSP90B1 | c.1173A>G p.T391= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs1213182978; called by muse, mutect2, varscan2
- IGHE | c.711C>A p.I237= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- MAP2 | c.945T>C p.S315= | Silent (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- MUC5B | c.16614C>A p.G5538= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs540837204; called by muse, mutect2, varscan2
- NMNAT2 | c.69G>A p.G23= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1308179131; called by muse, mutect2
- OR4C12 | c.222T>C p.S74= | Silent (SNP) | VAF 18/78 reads (23%) | called by muse, mutect2, varscan2
- OR52I2 | c.156T>G p.S52= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs763808672; called by muse, mutect2, varscan2
- PLEKHA7 | c.375G>A p.T125= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs145257579, COSV63044896; called by muse, mutect2, varscan2
- POSTN | c.1986A>G p.K662= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV101123503, COSV65713396; called by muse, mutect2, varscan2
- PTPRB | c.408C>T p.S136= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs751771260; called by muse, mutect2, varscan2
- SEMA5A | c.2250C>A p.I750= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV66786941; called by muse, mutect2, varscan2
- SGO2 | c.220A>C p.R74= | Silent (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- TEAD4 | c.69C>T p.T23= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs149191988; called by muse, mutect2, varscan2
- TPCN1 | c.1489C>T p.L497= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- TRIM63 | c.570G>A p.Q190= | Silent (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- KNOP1P1 | n.59T>C | RNA (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- ZNF658B | n.1008A>C | RNA (SNP) | VAF 22/145 reads (15%) | called by muse, mutect2, varscan2
